Somatic mutation profile of tumor specimen C3L-00581-03 (aliquot CPT0007410009) from CPTAC case C3L-00581, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.6 years (19,213 days).
Specimen C3L-00581-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d5c0aec-865d-40e9-b6bb-a3bde7ae6f0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00581-31 (Blood Derived Normal), aliquot CPT0002780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60c248e6-96ec-4864-9a4e-174056a7225e

The open-access MAF lists 112 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 19, Intron 9, Frame Shift Del 9, Frame Shift Ins 4, 5'UTR 3, Splice Site 3, Nonsense Mutation 3, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1416del p.S473Vfs*98 | Frame Shift Del (DEL) | VAF 72/324 reads (22%) | catalogued as rs1060503731; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADD2 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV52459516; called by muse, mutect2
- BICC1 | c.2445C>A p.N815K | Missense Mutation (SNP) | VAF 106/542 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99570989; called by muse, mutect2, varscan2
- CLPTM1L | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as rs762247898; called by muse, mutect2, varscan2
- DNAH2 | c.4045G>T p.E1349* | Nonsense Mutation (SNP) | VAF 25/122 reads (20%) | catalogued as COSV66727272; called by muse, mutect2, varscan2
- ERCC3 | c.2263G>C p.D755H | Missense Mutation (SNP) | VAF 176/793 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV53425589; called by muse, mutect2, varscan2
- FLG2 | c.6790C>T p.H2264Y | Missense Mutation (SNP) | VAF 148/892 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs770971156; called by muse, mutect2, varscan2
- GPCPD1 | c.1841G>A p.W614* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as rs192456172; called by muse, varscan2
- MYO3A | c.3576G>A p.M1192I | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56349084; called by muse, mutect2, varscan2
- PYGL | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 29/674 reads (4%) | catalogued as rs1327581647; called by muse, mutect2
- RFTN2 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.046); catalogued as rs189615528; called by muse, mutect2, varscan2
- RTN1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1014346787, COSV50718522; called by muse, mutect2, varscan2
- SCGB3A2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 64/578 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs774802794; called by muse, mutect2, varscan2
- SFSWAP | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 153/668 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs1170451411; called by muse, mutect2, varscan2
- SLC30A3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 38/853 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs771149305, COSV51985661, COSV51986814; called by muse, mutect2
- STEAP4 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1326771233; called by muse, mutect2, varscan2
- THEMIS | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 109/553 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs765387427, COSV100965532, COSV64070629; called by muse, mutect2, varscan2
- ZNF267 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV56256255; called by muse, mutect2, varscan2
- ZNF536 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 210/1003 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62821960; called by muse, mutect2, varscan2
- ZNF852 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101465013; called by muse, mutect2
- A2ML1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- ANKRD26 | c.2171G>T p.S724I | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- AQR | c.3894A>C p.R1298S | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATXN2L | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- BPIFB6 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 102/518 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CC2D1A | c.2074-2A>G p.X692_splice | Splice Site (SNP) | VAF 79/420 reads (19%) | called by muse, mutect2, varscan2
- CDH2 | c.439T>A p.F147I | Missense Mutation (SNP) | VAF 111/410 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK10 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 91/653 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- COL7A1 | c.2142_2148del p.Y715Ffs*37 | Frame Shift Del (DEL) | VAF 172/782 reads (22%) | called by mutect2, pindel, varscan2
- CPNE5 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CSAG3 | c.65del p.K22Rfs*9 | Frame Shift Del (DEL) | VAF 70/469 reads (15%) | called by mutect2, pindel, varscan2
- CST7 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 23/479 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2
- CTBP1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- DKK4 | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 93/469 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.9739G>C p.D3247H | Missense Mutation (SNP) | VAF 173/817 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- FAM83B | c.1098T>G p.F366L | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.053); called by muse, mutect2
- GSDMC | c.301A>C p.I101L | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM2 | c.307C>A p.P103T (on ENST00000394468 / NM_001039372.4; = p.P91T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/668 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICAM5 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNA10 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 99/482 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KLHL22 | c.261del p.E87Dfs*6 | Frame Shift Del (DEL) | VAF 39/236 reads (17%) | called by mutect2, pindel, varscan2
- KPNB1 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 115/596 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- LPIN1 | c.482dup p.S162Vfs*10 | Frame Shift Ins (INS) | VAF 82/670 reads (12%) | called by mutect2, pindel, varscan2
- LTBP1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LY75 | c.1344T>G p.D448E | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- MCTP1 | c.2449del p.V817Lfs*9 | Frame Shift Del (DEL) | VAF 97/703 reads (14%) | called by mutect2, pindel, varscan2
- NUP188 | c.2254C>A p.L752M | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- OR6C74 | c.332_333del p.F111Sfs*8 | Frame Shift Del (DEL) | VAF 22/132 reads (17%) | called by mutect2, pindel, varscan2
- PCDHB2 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); called by muse, mutect2
- PLEKHA6 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PRG4 | c.3497_3498insT p.G1167Rfs*21 | Frame Shift Ins (INS) | VAF 106/688 reads (15%) | called by mutect2, pindel*, varscan2
- PRRC2C | c.8200-1G>A p.X2734_splice (on ENST00000367742; = p.X2732_splice on NM_015172.4) | Splice Site (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- RCBTB2 | c.103del p.S35Pfs*10 | Frame Shift Del (DEL) | VAF 54/324 reads (17%) | called by mutect2, pindel, varscan2
- RYR2 | c.2679G>C p.W893C | Missense Mutation (SNP) | VAF 83/430 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA7A | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SH3GL1 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 264/1501 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SMC1B | c.759A>C p.R253S | Missense Mutation (SNP) | VAF 91/457 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SNX13 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SORL1 | c.4407del p.R1470Dfs*43 | Frame Shift Del (DEL) | VAF 110/668 reads (16%) | called by mutect2, pindel, varscan2
- SPP1 | c.404A>G p.D135G (on ENST00000395080 / NM_001040058.2; = p.D121G on NM_000582.2) | Missense Mutation (SNP) | VAF 146/675 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STOML2 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 53/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SYTL2 | c.584-2A>G p.X195_splice | Splice Site (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2, varscan2
- TNKS2 | c.910dup p.T304Nfs*8 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- TONSL | c.4055T>C p.L1352P | Missense Mutation (SNP) | VAF 90/401 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TTN | c.45527T>G p.I15176S (on ENST00000591111; = p.I7752S on NM_003319.4) | Missense Mutation (SNP) | VAF 12/330 reads (4%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- UFSP2 | c.727_728del p.F243Qfs*4 | Frame Shift Del (DEL) | VAF 53/265 reads (20%) | called by mutect2, pindel, varscan2
- UHRF2 | c.1811T>G p.L604W | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VHL | c.413dup p.S139Ifs*5 | Frame Shift Ins (INS) | VAF 124/604 reads (21%) | called by mutect2, pindel, varscan2
- XRN2 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZBTB48 | c.1459C>A p.H487N | Missense Mutation (SNP) | VAF 81/494 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H12C | c.285T>A p.N95K | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP3 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF26 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF33A | c.1774A>G p.K592E (on ENST00000458705 / NM_006974.3; = p.K593E on NM_006954.2) | Missense Mutation (SNP) | VAF 92/431 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ZNF568 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- ZNF583 | c.1362T>G p.H454Q | Missense Mutation (SNP) | VAF 82/379 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF692 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ZSCAN2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 123/731 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARMC7 | c.462C>T p.A154= | Silent (SNP) | VAF 180/892 reads (20%) | called by muse, mutect2, varscan2
- BCR | c.1164C>T p.C388= | Silent (SNP) | VAF 68/475 reads (14%) | called by muse, mutect2, varscan2
- GPR21 | c.1011A>G p.T337= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as rs1431892578; called by mutect2, varscan2
- HOXB4 | c.57A>C p.P19= | Silent (SNP) | VAF 201/1173 reads (17%) | catalogued as rs1205895976, COSV60177977; called by muse, mutect2, varscan2
- KCNQ1 | c.1866C>A p.G622= | Silent (SNP) | VAF 98/413 reads (24%) | called by muse, mutect2, varscan2
- KIF20A | c.546G>A p.R182= | Silent (SNP) | VAF 81/464 reads (17%) | catalogued as rs1483175198; called by muse, mutect2, varscan2
- LRRC8D | c.1662C>T p.A554= | Silent (SNP) | VAF 58/277 reads (21%) | catalogued as rs574691834; called by muse, mutect2, varscan2
- MLXIP | c.2530C>T p.L844= | Silent (SNP) | VAF 93/458 reads (20%) | called by muse, mutect2, varscan2
- PDIA5 | c.807T>C p.T269= | Silent (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- PKP3 | c.687G>T p.L229= | Silent (SNP) | VAF 205/967 reads (21%) | called by muse, mutect2, varscan2
- RSC1A1 | c.909T>C p.D303= | Silent (SNP) | VAF 49/158 reads (31%) | called by muse, mutect2, varscan2
- SEC14L1 | c.2059C>T p.L687= | Silent (SNP) | VAF 62/372 reads (17%) | catalogued as rs377362452; called by muse, mutect2, varscan2
- SLC13A2 | c.153T>C p.T51= | Silent (SNP) | VAF 84/509 reads (17%) | called by muse, mutect2, varscan2
- STEAP4 | c.177C>A p.P59= | Silent (SNP) | VAF 60/302 reads (20%) | called by muse, mutect2, varscan2
- STOML2 | c.219C>A p.I73= | Silent (SNP) | VAF 55/421 reads (13%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.2478G>A p.A826= | Silent (SNP) | VAF 127/705 reads (18%) | catalogued as rs372465003; called by muse, mutect2, varscan2
- UHRF2 | c.1810T>C p.L604= | Silent (SNP) | VAF 70/349 reads (20%) | called by muse, mutect2, varscan2
- VPS13D | c.4170G>A p.R1390= | Silent (SNP) | VAF 55/206 reads (27%) | called by muse, mutect2, varscan2
- ZNF560 | c.414G>C p.V138= | Silent (SNP) | VAF 45/230 reads (20%) | catalogued as rs908903278; called by muse, mutect2, varscan2
- ANKRD20A8P | n.1528A>C | RNA (SNP) | VAF 96/573 reads (17%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10087G>C | Intron (SNP) | VAF 235/1146 reads (21%) | called by muse, mutect2, varscan2
- CHKB | c.224+51C>T | Intron (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- COPS7A | c.163-252_163-238del | Intron (DEL) | VAF 21/211 reads (10%) | called by mutect2, pindel
- EIF4G3 | c.299+11C>T | Intron (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- FOXM1 | c.1021-9C>G | Intron (SNP) | VAF 92/392 reads (23%) | called by muse, mutect2, varscan2
- GFI1 | c.-5C>T | 5'UTR (SNP) | VAF 195/1014 reads (19%) | called by muse, mutect2, varscan2
- GJD4 | c.-29C>A | 5'UTR (SNP) | VAF 34/628 reads (5%) | catalogued as COSV100397206; called by muse, mutect2
- HADH | c.133-4891G>C | Intron (SNP) | VAF 83/578 reads (14%) | called by muse, mutect2, varscan2
- HMGN1 | chr21:39349475 C>G | 5'Flank (SNP) | VAF 24/153 reads (16%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.-11A>G | 5'UTR (SNP) | VAF 42/279 reads (15%) | catalogued as rs1208399434; called by muse, mutect2, varscan2
- RGS11 | c.658-16A>T | Intron (SNP) | VAF 55/309 reads (18%) | called by muse, mutect2, varscan2
- SH3TC1 | c.481+609C>G | Intron (SNP) | VAF 60/338 reads (18%) | called by muse, mutect2, varscan2
- WDR11 | c.*32G>A | 3'UTR (SNP) | VAF 79/537 reads (15%) | called by muse, mutect2, varscan2
- ZNF880 | c.269-4338T>C | Intron (SNP) | VAF 33/164 reads (20%) | catalogued as rs1338089749; called by muse, mutect2, varscan2
